Somatic mutation profile of tumor specimen TCGA-UY-A9PD-01A (aliquot TCGA-UY-A9PD-01A-11D-A38G-08) from TCGA case TCGA-UY-A9PD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.9 years (29,565 days).
Specimen TCGA-UY-A9PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fdf1fe1-7a5b-4258-bde3-18e0f8c1702d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A9PD-10A (Blood Derived Normal), aliquot TCGA-UY-A9PD-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0e8c4c5-375c-4ef9-8035-84c7caeab51c

The open-access MAF lists 331 somatic variants for this specimen: 243 protein-altering or splice-affecting, 81 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 81, Nonsense Mutation 16, Frame Shift Del 7, Intron 4, Splice Site 3, Splice Region 2, Frame Shift Ins 2, 3'Flank 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs72653794, CM053078, COSV52741966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; called by muse, mutect2, varscan2
- TP53 | c.742C>G p.R248G | Missense Mutation (SNP) | VAF 19/59 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.2646C>A p.Y882* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV99657579; called by muse, mutect2, varscan2
- AC131160.1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV57700235; called by muse, mutect2, varscan2
- ADAMTS19 | c.2938C>T p.Q980* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as rs1452053716, COSV99180624; called by muse, mutect2, varscan2
- ADAMTS20 | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280909384, COSV67129101, COSV67132697; called by muse, mutect2, varscan2
- ADGRB2 | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57071626; called by muse, mutect2, varscan2
- AGGF1 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57228217; called by muse, mutect2, varscan2
- ALMS1 | c.9157C>T p.P3053S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52505442; called by muse, mutect2
- AMOTL2 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51438288; called by muse, mutect2, varscan2
- ANKRD52 | c.2590G>C p.A864P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57283229; called by muse, mutect2, varscan2
- ANXA3 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1359809932; called by muse, mutect2, varscan2
- APBB1IP | c.345T>A p.N115K | Missense Mutation (SNP) | VAF 100/178 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV63301861; called by muse, mutect2, varscan2
- ARHGAP33 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV50120157; called by muse, mutect2, varscan2
- ARHGAP35 | c.1874A>G p.K625R | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV68329849; called by muse, mutect2, varscan2
- ARNTL | c.1127A>C p.Y376S (on ENST00000403290 / NM_001297719.2; = p.Y375S on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV62985758; called by muse, mutect2, varscan2
- ASCC1 | c.631G>A p.G211R (on ENST00000342444 / NM_001369085.1; = p.G183R on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1192378610, COSV57725777; called by muse, mutect2, varscan2
- ASIC5 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV72232505; called by muse, mutect2, varscan2
- ASPM | c.9243dup p.S3082Ifs*42 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | catalogued as rs749449214; called by mutect2, pindel, varscan2
- ATP11A | c.1605A>G p.I535M | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1485223010, COSV52108108; called by muse, mutect2, varscan2
- AURKB | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs750194641, COSV60243934; called by muse, varscan2
- BEND3 | c.2309A>G p.K770R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV64680351; called by muse, mutect2, varscan2
- BICRAL | c.2518G>T p.G840C | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV58404263; called by muse, mutect2, varscan2
- BPTF | c.5419G>C p.E1807Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV58833735; called by muse, mutect2, varscan2
- C11orf24 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.162); catalogued as COSV58505201; called by muse, mutect2, varscan2
- CACHD1 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV51550303; called by mutect2, varscan2
- CACNA1C | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1188941301, COSV100222167; called by muse, mutect2, varscan2
- CACNA1E | c.6815T>G p.L2272R (on ENST00000367573 / NM_001205293.3; = p.L2229R on NM_000721.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV62385849; called by muse, mutect2, varscan2
- CADPS | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51871943; called by muse, mutect2, varscan2
- CAMSAP2 | c.3918G>C p.K1306N (on ENST00000236925 / NM_001297707.2; = p.K1295N on NM_203459.3) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV52668105; called by muse, mutect2, varscan2
- CCDC178 | c.1673T>A p.I558N | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1473704775, COSV55765383; called by muse, mutect2, varscan2
- CDH18 | c.188T>C p.L63S | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56909683, COSV56917444; called by muse, mutect2, varscan2
- CDK12 | c.3425C>G p.S1142C | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as COSV70999811; called by muse, mutect2, varscan2
- CDK9 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs868437001, COSV64723549; called by muse, mutect2, varscan2
- CEP290 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.578); catalogued as rs1163798418, COSV100469861; called by muse, mutect2, varscan2
- CFTR | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as rs1478315064, CM1212240, COSV99139724; called by muse, mutect2, varscan2
- CHD6 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as COSV100498701; called by muse, mutect2
- CLMP | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71649434; called by muse, varscan2
- COL16A1 | c.2583A>G p.P861= | Splice Region (SNP) | VAF 11/57 reads (19%) | catalogued as COSV54702292; called by muse, mutect2, varscan2
- COL25A1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67647878; called by muse, mutect2, varscan2
- COTL1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200837618, COSV52289737; called by muse, mutect2, varscan2
- DAB2 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV57913111; called by muse, mutect2, varscan2
- DDB1 | c.1302-1G>A p.X434_splice | Splice Site (SNP) | VAF 27/146 reads (18%) | catalogued as COSV57101711; called by muse, mutect2, varscan2
- DDX1 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51838678; called by muse, mutect2, varscan2
- DDX1 | c.1438A>G p.N480D | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV51838691; called by muse, mutect2, varscan2
- DENND2A | c.1978C>A p.R660S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52047457, COSV52048964; called by muse, mutect2, varscan2
- DHX35 | c.1644G>A p.M548I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV52668612; called by muse, mutect2, varscan2
- DMBT1 | c.4942C>T p.R1648* (on ENST00000338354 / NM_001377530.1; = p.R891* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 96/422 reads (23%) | catalogued as rs746471340, COSV100351779; called by muse, mutect2, varscan2
- DNAH6 | c.1602G>A p.L534= | Splice Region (SNP) | VAF 23/162 reads (14%) | catalogued as COSV52853558; called by muse, mutect2, varscan2
- DNAH6 | c.1810A>T p.I604F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV52853583; called by muse, mutect2
- DSG1 | c.2417C>T p.T806I | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57134046; called by muse, mutect2, varscan2
- DSG2 | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs1481718957, COSV55197821; called by muse, mutect2, varscan2
- EPHX2 | c.1238A>G p.D413G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV66844179; called by muse, mutect2
- ERICH3 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV58602120, COSV58614446; called by muse, mutect2, varscan2
- ERLIN2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs771074780, COSV52419882; called by muse, mutect2, varscan2
- EVL | c.860A>T p.K287M (on ENST00000402714 / NM_001330221.2; = p.K289M on NM_016337.3) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV67374613; called by muse, mutect2, varscan2
- FAHD2B | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1209696678, COSV55630232; called by muse, varscan2
- FAM135B | c.1646del p.P549Qfs*3 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as COSV99425000; called by mutect2, pindel, varscan2
- FANK1 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV64126014; called by muse, mutect2, varscan2
- FAT3 | c.6535G>A p.V2179I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV53089284; called by muse, mutect2
- FAT4 | c.14863C>T p.L4955F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58676175; called by muse, mutect2
- FBXO32 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs1193372337, COSV54890492; called by muse, mutect2, varscan2
- FLG | c.9634G>A p.G3212R | Missense Mutation (SNP) | VAF 67/445 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV100912192; called by muse, mutect2
- FZD10 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1163931148, COSV57472609; called by muse, mutect2, varscan2
- GANAB | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV55488140; called by muse, mutect2
- GFRAL | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 50/84 reads (60%) | catalogued as COSV100475931; called by muse, mutect2, varscan2
- GNAZ | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV50737306; called by muse, mutect2, varscan2
- GOLGA4 | c.5803del p.A1935Qfs*22 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | catalogued as COSV62714909; called by mutect2, pindel, varscan2
- GPNMB | c.1002A>T p.K334N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.156); catalogued as COSV51697457; called by muse, mutect2, varscan2
- GPR50 | c.30del p.Y11Mfs*17 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs1412998291, COSV54437405; called by mutect2, pindel, varscan2
- GSK3A | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV55898720; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV57030388; called by muse, mutect2, varscan2
- H2AC13 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV100704385, COSV62440550; called by muse, mutect2, varscan2
- HIPK3 | c.3271A>G p.T1091A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57561527; called by muse, mutect2, varscan2
- HIRA | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286190013, COSV54271937, COSV54278306; called by muse, mutect2, varscan2
- HMGCS2 | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs779280964, COSV65567474; called by muse, mutect2
- HMSD | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV68816833; called by muse, mutect2, varscan2
- HNRNPA0 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV59246451; called by muse, mutect2, varscan2
- HS3ST2 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 30/141 reads (21%) | catalogued as COSV99758572; called by muse, mutect2, varscan2
- HSPG2 | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV65979239; called by muse, mutect2
- HUNK | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.065); catalogued as rs992502321, COSV54225842; called by muse, mutect2, varscan2
- ICA1 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55577131; called by muse, mutect2, varscan2
- IGHG2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs757878182; called by muse, mutect2, varscan2
- IGSF1 | c.1323C>A p.C441* | Nonsense Mutation (SNP) | VAF 30/41 reads (73%) | catalogued as COSV100812325, COSV63840366; called by muse, mutect2, varscan2
- IGSF3 | c.1655G>C p.R552P (on ENST00000369486 / NM_001007237.3; = p.R572P on NM_001542.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605086, COSV59596370; called by muse, mutect2, varscan2
- IK | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101341821; called by muse, mutect2, varscan2
- IL13RA1 | c.974A>T p.K325I | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV65424278; called by muse, mutect2, varscan2
- IL17REL | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1021422002, COSV58007682; called by muse, mutect2, varscan2
- IRGC | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs1372475411, COSV54983331; called by muse, mutect2, varscan2
- KALRN | c.4457C>T p.P1486L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758552417, COSV53756698, COSV53770333; called by muse, mutect2, varscan2
- KAT6A | c.4866C>G p.S1622R | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as COSV55904347; called by muse, mutect2, varscan2
- KCNC4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63925284, COSV99056742; called by muse, mutect2, varscan2
- KDM6A | c.3715T>C p.W1239R | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65038311; called by muse, mutect2, varscan2
- KIF5B | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56651335; called by muse, mutect2, varscan2
- KLHL1 | c.1603G>T p.V535F | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.392); catalogued as COSV64768847; called by muse, mutect2
- KLHL18 | c.1662G>T p.M554I | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV51744617; called by muse, mutect2, varscan2
- KLRG2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs930847497, COSV61800500; called by muse, mutect2, varscan2
- KMT2A | c.10754G>A p.G3585E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV63283562; called by muse, mutect2, varscan2
- KRT73 | c.1613C>T p.T538I | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV59838380; called by muse, mutect2, varscan2
- KRTAP4-5 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV58351906; called by muse, mutect2
- LENG8 | c.1931A>C p.Q644P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58726666; called by muse, mutect2, varscan2
- LHFPL3 | c.469A>T p.M157L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV67807905; called by muse, varscan2
- LMNB2 | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs991731164, COSV53113934; called by muse, mutect2, varscan2
- LRP1 | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as rs137909502; called by muse, mutect2, varscan2
- LRP1B | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV67198714; called by muse, mutect2, varscan2
- LRRC32 | c.346A>G p.S116G | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52632127; called by muse, mutect2, varscan2
- LTN1 | c.2689C>T p.H897Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV63733303; called by muse, mutect2, varscan2
- MACF1 | c.18754G>T p.D6252Y (on ENST00000372915; = p.D4297Y on NM_012090.5) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | catalogued as COSV57112059; called by muse, mutect2
- MAGEA6 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61448782; called by muse, mutect2, varscan2
- MAN2A1 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV54846855, COSV54847102; called by muse, mutect2, varscan2
- MAP6 | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1202721889, COSV100496902; called by muse, mutect2
- MARVELD3 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs1162045720, COSV51705749; called by muse, mutect2, varscan2
- MCAM | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs760226793, COSV50631849, COSV50669021; called by muse, mutect2, varscan2
- MCOLN3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs771354010, COSV100352995; called by muse, mutect2
- MED1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.905); catalogued as COSV56123174; called by muse, mutect2, varscan2
- METTL2B | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV99299999; called by muse, mutect2, varscan2
- MFGE8 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV51555566; called by muse, mutect2, varscan2
- MFN2 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52421128; called by muse, mutect2, varscan2
- MFSD14A | c.806dup p.L269Ffs*43 | Frame Shift Ins (INS) | VAF 32/96 reads (33%) | catalogued as rs780635289; called by mutect2, varscan2
- MIPOL1 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59381062; called by muse, mutect2, varscan2
- MKLN1 | c.1715C>A p.P572Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV61760286; called by muse, mutect2, varscan2
- MORC1 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51716475; called by muse, mutect2, varscan2
- MS4A10 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100382430, COSV57633450; called by muse, mutect2
- MTTP | c.2234C>G p.S745C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55504598; called by muse, mutect2, varscan2
- MXRA5 | c.1381C>G p.Q461E | Missense Mutation (SNP) | VAF 95/118 reads (81%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV54228590; called by muse, mutect2, varscan2
- MYG1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as COSV52932460; called by muse, mutect2, varscan2
- MYO15A | c.5261G>A p.R1754H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs544020493, COSV52753726; called by muse, mutect2, varscan2
- NAMPT | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV55994566; called by muse, mutect2, varscan2
- NAT16 | c.14C>A p.A5D | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs767752008, COSV55864374; called by muse, mutect2, varscan2
- NBAS | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55715936; called by muse, mutect2, varscan2
- NCAM2 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs376541267, COSV53089218; called by muse, mutect2, varscan2
- NCKAP1 | c.2057G>T p.C686F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62940302; called by muse, mutect2, varscan2
- NCOA6 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs947932096, COSV62862132; called by muse, mutect2, varscan2
- NCOR1 | c.6556G>A p.G2186R | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV51966078; called by muse, mutect2, varscan2
- NCOR1 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51966098; called by muse, mutect2, varscan2
- NDUFAF3 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58244329; called by muse, mutect2, varscan2
- NEMF | c.1751C>A p.P584H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1210880858, COSV53589969; called by muse, mutect2, varscan2
- NEU3 | c.1070C>G p.P357R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV53636007; called by muse, mutect2, varscan2
- NLRP5 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1170230276, COSV66762996; called by muse, mutect2, varscan2
- NMU | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51699136, COSV51700634; called by muse, mutect2, varscan2
- NPHP1 | c.2194G>T p.V732L (on ENST00000393272 / NM_207181.4; = p.V733L on NM_000272.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV57207270; called by muse, mutect2, varscan2
- NRAS | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV54741072; called by muse, mutect2, varscan2
- NRG1 | c.639A>T p.Q213H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV55152015; called by muse, mutect2, varscan2
- NTNG1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53965690; called by muse, mutect2, varscan2
- NWD1 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs758051323, COSV60339292; called by muse, mutect2, varscan2
- NXPH1 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV68312539; called by muse, mutect2, varscan2
- OBSCN | c.23197G>A p.A7733T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs776477020, COSV100805551; called by muse, varscan2
- OCA2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62341489; called by muse, mutect2, varscan2
- OR2B11 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.48); catalogued as COSV59509634; called by mutect2, varscan2
- OR2G2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV60739814; called by muse, mutect2, varscan2
- OR2Z1 | c.680G>C p.S227T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV60691954; called by muse, mutect2, varscan2
- OR51E2 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201945969, COSV67807056; called by muse, mutect2, varscan2
- OR6B1 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs750570667, COSV68769916; called by muse, mutect2, varscan2
- OR6C6 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV64455580; called by muse, mutect2, varscan2
- OR8D1 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV63441859; called by muse, mutect2, varscan2
- OSBPL9 | c.934A>T p.I312L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61867722; called by muse, mutect2, varscan2
- OVCH1 | c.2375G>A p.W792* | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | catalogued as COSV100549206; called by muse, mutect2, varscan2
- PCDHB12 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as COSV53394216, COSV53396526; called by muse, mutect2, varscan2
- PLCD1 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs773011878, COSV100587429, COSV100587744; called by muse, varscan2
- PLEKHG2 | c.2666A>G p.E889G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV52680009; called by muse, mutect2, varscan2
- PLEKHH2 | c.313_314del p.L105Gfs*5 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | catalogued as COSV56750999; called by mutect2, pindel, varscan2
- POLR2C | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs1375772364, COSV99345990; called by muse, mutect2, varscan2
- POT1 | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV62928777; called by muse, mutect2, varscan2
- PPT2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751977544, COSV52997718; called by muse, mutect2, varscan2
- PRAMEF10 | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99339198; called by muse, mutect2, varscan2
- PRC1 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV62694530; called by muse, mutect2, varscan2
- PREX2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376775544; called by muse, mutect2, varscan2
- PRR14 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV54911087; called by muse, varscan2
- PSG5 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 135/509 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.532); catalogued as COSV61653735; called by muse, mutect2, varscan2
- PTCHD4 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.171); catalogued as rs370904351; called by muse, mutect2, varscan2
- PTH2R | c.55T>A p.C19S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55914752; called by muse, mutect2, varscan2
- PTPRU | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as rs769583142, COSV60523418, COSV60523886; called by muse, mutect2, varscan2
- R3HDM1 | c.993-1G>A p.X331_splice | Splice Site (SNP) | VAF 18/100 reads (18%) | catalogued as COSV51522241; called by muse, mutect2, varscan2
- R3HDM1 | c.2063C>G p.P688R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV51522254; called by muse, mutect2, varscan2
- RAB11B | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.23); catalogued as rs937126014, COSV60085397; called by muse, mutect2, varscan2
- RABL3 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99382166, COSV99382169; called by muse, mutect2, varscan2
- RAD51AP2 | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV67587594, COSV67589219; called by muse, mutect2, varscan2
- RBM26 | c.2555C>T p.S852L (on ENST00000438737 / NM_001366735.2; = p.S825L on NM_022118.5) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV57392636; called by muse, mutect2, varscan2
- RELN | c.4021G>T p.A1341S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.928); catalogued as COSV58991769; called by muse, mutect2, varscan2
- RGS18 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as rs1489421220, COSV100817904; called by muse, mutect2, varscan2
- RGS21 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV69881760; called by muse, mutect2, varscan2
- RNF186 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64296713; called by muse, mutect2
- ROBO1 | c.3886G>A p.V1296M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV71392647; called by muse, mutect2, varscan2
- RP1L1 | c.6112G>T p.E2038* | Nonsense Mutation (SNP) | VAF 53/162 reads (33%) | catalogued as COSV101223620; called by muse, mutect2, varscan2
- RSBN1L | c.1079C>A p.S360* | Nonsense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as COSV100616231; called by muse, mutect2, varscan2
- S1PR2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1363334635, COSV58485236; called by muse, mutect2, varscan2
- SCAMP5 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62643133; called by muse, mutect2, varscan2
- SCN1A | c.3262A>G p.T1088A (on ENST00000303395 / NM_001202435.3; = p.T1077A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.042); catalogued as COSV57664268; called by muse, mutect2, varscan2
- SCN1A | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as CM147001, COSV57658506, COSV57664296; called by muse, mutect2, varscan2
- SF3B1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV59209961; called by muse, mutect2, varscan2
- SFTPA2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs751514531, COSV64882314; called by muse, mutect2, varscan2
- SH3D19 | c.1699T>A p.S567T | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV58789695; called by muse, mutect2, varscan2
- SLC10A1 | c.385T>C p.C129R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV53682068; called by muse, mutect2, varscan2
- SLC24A4 | c.1262G>C p.R421T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV54109500; called by muse, mutect2, varscan2
- SLC26A8 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs754809213, COSV62885083; called by muse, mutect2, varscan2
- SLC29A4 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148542712, COSV99786930; called by muse, mutect2
- SLC39A7 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs778401742, COSV63399573; called by muse, mutect2, varscan2
- SLC44A2 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV59835702; called by muse, mutect2, varscan2
- SLC6A1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs1490096672, COSV55114041; called by muse, mutect2, varscan2
- SPP1 | c.742C>T p.R248W (on ENST00000395080 / NM_001040058.2; = p.R234W on NM_000582.2) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs768101938, COSV52951533; called by muse, mutect2, varscan2
- SPTBN4 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV58945629; called by muse, mutect2, varscan2
- SRRM4 | c.559C>A p.R187S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs201423492, COSV57411406; called by muse, mutect2, varscan2
- STAB1 | c.6530C>T p.S2177L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs763192280, COSV58733618; called by muse, mutect2
- STAU2 | c.811G>C p.E271Q (on ENST00000524300 / NM_001164380.2; = p.E239Q on NM_014393.2) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.62); catalogued as COSV63307332; called by muse, mutect2, varscan2
- SYNJ1 | c.4357G>A p.G1453R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.096); catalogued as COSV59145891; called by muse, mutect2
- TAF1 | c.4306A>G p.S1436G (on ENST00000373790 / NM_138923.4; = p.S1457G on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52109471; called by muse, mutect2, varscan2
- TBC1D9B | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100783653; called by muse, mutect2
- TDG | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); catalogued as COSV57165513; called by muse, mutect2, varscan2
- TIGAR | c.769A>G p.M257V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754839056, COSV51627186; called by muse, mutect2, varscan2
- TMEM131 | c.2126G>C p.R709P | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); catalogued as COSV51772090; called by muse, mutect2, varscan2
- TONSL | c.1627C>A p.R543S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV101340151, COSV68047905, COSV68048412; called by muse, mutect2, varscan2
- TPR | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV66600166; called by muse, mutect2, varscan2
- TPRG1 | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100800863; called by muse, mutect2, varscan2
- TRMT5 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV50781557; called by mutect2, varscan2
- TRPC4 | c.2666G>T p.R889L (on ENST00000379705 / NM_016179.4; = p.R894L on NM_003306.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs761582713, COSV100157457, COSV58994204; called by muse, mutect2, varscan2
- TSHZ3 | c.2176C>A p.Q726K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53667013; called by muse, mutect2, varscan2
- TUBB6 | c.320C>G p.T107R | Missense Mutation (SNP) | VAF 111/139 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV52313268, COSV52313274; called by muse, mutect2, varscan2
- UBASH3A | c.1900T>C p.W634R | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780652404, COSV52311214; called by muse, mutect2, varscan2
- UNC45B | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52093409; called by muse, mutect2, varscan2
- UNC5D | c.947A>T p.E316V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV54778774; called by muse, mutect2, varscan2
- UPK2 | c.84C>A p.N28K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV50628837; called by muse, mutect2, varscan2
- VPS13B | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV62017383; called by muse, mutect2, varscan2
- VPS9D1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV99235340; called by muse, mutect2, varscan2
- WT1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV60068623; called by muse, mutect2
- XKR7 | c.1116G>A p.W372* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1465818750, COSV73813328; called by muse, mutect2
- XPO6 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs746079866, COSV58964481; called by muse, mutect2, varscan2
- XPOT | c.2749C>T p.Q917* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as rs1216740348, COSV100225758; called by muse, mutect2, varscan2
- ZEB1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435892827, COSV58039648, COSV58051236; called by muse, mutect2, varscan2
- ZFP69B | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64315099; called by muse, mutect2, varscan2
- ZMIZ1 | c.3056G>C p.G1019A | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.08); catalogued as COSV57891896; called by muse, mutect2, varscan2
- ZNF208 | c.3047T>A p.L1016H | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV68102410; called by muse, mutect2, varscan2
- ZNF563 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53369964; called by muse, mutect2, varscan2
- ZNF776 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV57814734; called by muse, mutect2, varscan2
- ZNF878 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1235849598, COSV72155950; called by muse, mutect2, varscan2
- ZP4 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63911448, COSV63913131; called by muse, mutect2, varscan2
- ANAPC1 | c.3789del p.T1264Qfs*14 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, varscan2
- COL7A1 | c.2439_2440+14del p.X813_splice | Splice Site (DEL) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- EPC1 | c.2267_2276delinsATTCA p.R756Hfs*22 | Frame Shift Del (DEL) | VAF 14/141 reads (10%) | called by pindel, varscan2*
- PRKCZ | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SEC24C | c.2238del p.V747Lfs*6 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- TAF15 | c.817C>G p.L273V (on ENST00000605844 / NM_139215.3; = p.L270V on NM_003487.4) | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMPRSS11F | c.158_160del p.V53del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by pindel, varscan2
- A1BG | c.387C>T p.I129= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as COSV54050300, COSV54050854; called by muse, mutect2, varscan2
- ADGRV1 | c.15381T>C p.N5127= | Silent (SNP) | VAF 65/111 reads (59%) | catalogued as rs1220919365, COSV67980851; called by muse, mutect2, varscan2
- AHNAK2 | c.10359G>A p.A3453= | Silent (SNP) | VAF 98/269 reads (36%) | catalogued as rs368303508; called by muse, mutect2, varscan2
- ANK2 | c.2670C>T p.S890= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52151887; called by muse, mutect2, varscan2
- ATP2A3 | c.2229C>T p.I743= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs762087979, COSV59227326; called by muse, mutect2, varscan2
- C12orf56 | c.1647G>C p.L549= (on ENST00000543942 / NM_001170633.2; = p.L389= on NM_001099676.3) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV61485955; called by muse, mutect2, varscan2
- C4orf17 | c.537G>A p.Q179= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs371184535; called by muse, mutect2, varscan2
- C7orf26 | c.801C>T p.V267= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV60418202; called by muse, mutect2, varscan2
- CAND2 | c.3348C>T p.D1116= (on ENST00000456430 / NM_001162499.2; = p.D999= on NM_012298.3) | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs754832586, COSV55988140; called by muse, mutect2, varscan2
- CCDC151 | c.987A>G p.L329= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as rs1388624564, COSV62697445; called by muse, mutect2, varscan2
- CD109 | c.738A>G p.L246= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV54646987, COSV99753817; called by muse, mutect2, varscan2
- CD200R1L | c.363G>T p.G121= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV68003976; called by muse, mutect2, varscan2
- CENPI | c.1263C>T p.I421= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV54501390; called by muse, mutect2, varscan2
- CNTNAP1 | c.645C>T p.A215= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1245765469, COSV52848713, COSV99226234; called by muse, mutect2, varscan2
- COL9A1 | c.144G>A p.R48= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV61830226; called by muse, mutect2, varscan2
- DIP2C | c.546G>A p.Q182= | Silent (SNP) | VAF 58/105 reads (55%) | catalogued as COSV55150606; called by muse, mutect2, varscan2
- DIS3L | c.2235T>C p.N745= (on ENST00000319212 / NM_001143688.3; = p.N662= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 76/168 reads (45%) | catalogued as COSV59911470; called by muse, mutect2, varscan2
- DUS1L | c.531C>T p.R177= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV57648041; called by muse, mutect2
- EGF | c.804A>T p.T268= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV54476976; called by muse, mutect2, varscan2
- EPPK1 | c.1542C>T p.L514= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1554661281, COSV101599954; called by muse, mutect2, varscan2
- FAF1 | c.1347G>T p.P449= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs750398957, COSV65636747, COSV65637211; called by muse, mutect2, varscan2
- FAM98C | c.855G>T p.L285= | Silent (SNP) | VAF 59/172 reads (34%) | catalogued as COSV53038366; called by muse, mutect2, varscan2
- FEZF1 | c.1356G>A p.T452= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1212740659, COSV58658351; called by muse, mutect2, varscan2
- FHIT | c.429G>T p.R143= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV59288616; called by muse, mutect2
- FOXA3 | c.543C>T p.S181= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56215229; called by muse, mutect2, varscan2
- FSHR | c.2028C>T p.P676= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs978748810, COSV58620032; called by muse, mutect2, varscan2
- GPAT4 | c.1162C>T p.L388= | Silent (SNP) | VAF 108/159 reads (68%) | catalogued as COSV67840462; called by muse, mutect2, varscan2
- GPR31 | c.96C>T p.N32= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs745982466, COSV64761241; called by muse, mutect2, varscan2
- HDAC9 | c.1201T>C p.L401= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV67769740; called by muse, mutect2, varscan2
- HMCN1 | c.8220C>T p.T2740= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as rs562987367, COSV54886135; called by muse, mutect2, varscan2
- IGF2BP1 | c.315T>C p.G105= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV51730030; called by muse, mutect2, varscan2
- IGSF21 | c.1116G>A p.P372= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs762194873, COSV52127730; called by muse, mutect2, varscan2
- ILF3 | c.2637C>T p.G879= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as rs766248749, COSV51555179; called by muse, mutect2, varscan2
- JPH4 | c.1110C>T p.A370= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100689391; called by muse, mutect2, varscan2
- KCNA1 | c.57C>T p.P19= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV66836874; called by muse, mutect2, varscan2
- KCNG1 | c.1269G>A p.T423= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs751377534, COSV65368527; called by muse, mutect2, varscan2
- KMT2E | c.411A>G p.K137= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs751745269, COSV57570994; called by muse, mutect2, varscan2
- KRTAP19-4 | c.21T>C p.Y7= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as rs760180234, COSV61858400; called by muse, mutect2, varscan2
- LTBP3 | c.3036C>T p.N1012= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs767751461, COSV54210833; called by muse, mutect2, varscan2
- MAGEB6B | c.84C>T p.P28= | Silent (SNP) | VAF 64/78 reads (82%) | catalogued as COSV69689611; called by muse, mutect2, varscan2
- MAP6 | c.90C>T p.F30= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs751504650, COSV100496900; called by muse, mutect2
- MFN2 | c.1101G>A p.Q367= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV52420726; called by muse, mutect2, varscan2
- MICU1 | c.873G>A p.L291= (on ENST00000361114 / NM_001195518.2; = p.L297= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100741929; called by muse, mutect2
- MIIP | c.735C>G p.V245= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV52427243, COSV52427789; called by muse, mutect2, varscan2
- MYOC | c.111C>A p.L37= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV50674150; called by muse, mutect2, varscan2
- NCAPD3 | c.2547C>T p.D849= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs984648180, COSV73257878; called by muse, mutect2, varscan2
- NCS1 | c.207C>T p.F69= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV64962241; called by muse, mutect2, varscan2
- NLRP12 | c.2589G>A p.L863= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV60744827; called by muse, mutect2, varscan2
- NPTN | c.1020C>G p.L340= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV54737134; called by muse, mutect2, varscan2
- NUAK1 | c.609C>T p.Y203= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV54601515; called by muse, mutect2, varscan2
- OR10J3 | c.147T>A p.I49= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as COSV59953870; called by muse, mutect2, varscan2
- OR4S1 | c.423G>C p.L141= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV60678869; called by muse, mutect2, varscan2
- PARP16 | c.552C>A p.T184= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56034878, COSV99975482; called by muse, mutect2, varscan2
- PCDHB12 | c.1746G>T p.P582= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as rs781806633, COSV53394225; called by muse, mutect2, varscan2
- PDCD6IP | c.2262C>T p.P754= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV56241940; called by muse, mutect2, varscan2
- PDIA6 | c.795C>G p.A265= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV55349749; called by muse, mutect2, varscan2
- PDZRN4 | c.702G>A p.L234= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV68402940; called by muse, mutect2, varscan2
- PHF3 | c.5277A>C p.A1759= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV50314916; called by muse, mutect2, varscan2
- PTH2R | c.1530C>T p.H510= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs762390560, COSV55914761, COSV55920577; called by muse, mutect2, varscan2
- PYDC1 | c.159C>T p.T53= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV57250818; called by muse, mutect2, varscan2
- PYGB | c.1029C>A p.P343= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs142521587, COSV53816690; called by muse, mutect2
- SCARA5 | c.69C>G p.S23= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV57276181, COSV57279196; called by muse, mutect2, varscan2
- SLC22A12 | c.576C>T p.F192= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs747260736, COSV60571326; called by muse, mutect2, varscan2
- SLCO1B1 | c.1341A>G p.P447= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV57008652; called by muse, mutect2, varscan2
- SLITRK3 | c.1620C>T p.L540= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1238276196, COSV53846561; called by muse, mutect2, varscan2
- SRP54 | c.66T>A p.I22= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99392848; called by muse, mutect2, varscan2
- SVOPL | c.1152C>T p.F384= (on ENST00000419765; = p.F232= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs753564328, COSV55989348; called by muse, mutect2
- SYT11 | c.1077C>T p.F359= | Silent (SNP) | VAF 220/470 reads (47%) | catalogued as COSV64173854; called by muse, mutect2, varscan2
- TFF1 | c.225C>T p.D75= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs142072140; called by muse, mutect2, varscan2
- TMEM175 | c.639G>A p.L213= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1176318950, COSV53278036; called by muse, mutect2, varscan2
- TOX | c.462G>A p.Q154= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as COSV63844059; called by muse, mutect2, varscan2
- TRMT11 | c.285G>A p.V95= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV57672368; called by muse, mutect2, varscan2
- TRPC5 | c.1422G>A p.P474= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1421671340, COSV53286582; called by muse, mutect2, varscan2
- TTLL1 | c.604C>T p.L202= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1013166857, COSV56738074; called by muse, mutect2, varscan2
- TTN | c.73122C>T p.V24374= (on ENST00000591111; = p.V16950= on NM_003319.4) | Silent (SNP) | VAF 52/88 reads (59%) | catalogued as COSV59944946; called by muse, mutect2, varscan2
- VIP | c.132G>A p.E44= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV65888679, COSV65889662; called by muse, mutect2, varscan2
- VPS13D | c.1713C>T p.V571= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs751136749, COSV62526988; called by muse, mutect2, varscan2
- VWA5A | c.1554C>T p.L518= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as COSV64412279, COSV64413782; called by muse, mutect2, varscan2
- XKR7 | c.1557G>A p.E519= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs1194157980, COSV73812948; called by muse, mutect2, varscan2
- ZNF623 | c.117G>A p.T39= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs201671001, COSV71697120; called by muse, mutect2, varscan2
- ZNF80 | c.360C>G p.L120= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV57360175; called by muse, mutect2
- AC092718.9 | chr16:81154257 C>T | 3'Flank (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097386 G>A | 3'Flank (SNP) | VAF 74/400 reads (19%) | catalogued as COSV63750890; called by muse, mutect2, varscan2
- BCL2A1 | c.420+3052C>T | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- GTF2A1 | c.338-1095C>T | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as rs1445972839, COSV99993563; called by muse, mutect2, varscan2
- MIR205 | n.30C>T | RNA (SNP) | VAF 67/132 reads (51%) | catalogued as rs533396228; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+561G>C | Intron (SNP) | VAF 18/76 reads (24%) | catalogued as COSV72102883; called by muse, mutect2, varscan2
- TCP10L3 | n.2719+1168G>A | Intron (SNP) | VAF 28/58 reads (48%) | catalogued as rs1273692070, COSV64750069; called by muse, mutect2, varscan2
